Somatic mutation profile of tumor specimen 0DDHV9 from CCDI case PBBNWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,834 days).
Specimen 0DDHV9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae16bc32-785c-4d12-9f7b-400c9612346d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDHVA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21e4b6bd-4e7b-4ea5-ba7d-3fcf54310497

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Site 2, 5'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF19 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 255/726 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs751574270, COSV54615614; called by muse, mutect2, varscan2
- OR4K1 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 54/480 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs776240917, COSV53460164; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 52/563 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2
- STAG1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 132/277 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52600207; called by muse, varscan2
- EMC2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KDM1A | c.1013-19_1025del p.X338_splice | Splice Site (DEL) | VAF 77/259 reads (30%) | called by mutect2, pindel, varscan2
- MRS2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC18A1 | c.814+1G>T p.X272_splice | Splice Site (SNP) | VAF 18/514 reads (4%) | called by muse, mutect2
- SYCP2 | c.1654_1657del p.N552* | Frame Shift Del (DEL) | VAF 47/278 reads (17%) | called by mutect2, pindel, varscan2
- FAM217A | c.-27A>G | 5'UTR (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- OR7G2 | chr19:9102205 ins A | 3'Flank (INS) | VAF 14/47 reads (30%) | catalogued as rs979278290; called by mutect2, varscan2
